Somatic mutation profile of tumor specimen TCGA-CX-A4AQ-01A (aliquot TCGA-CX-A4AQ-01A-11D-A25D-08) from TCGA case TCGA-CX-A4AQ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 56.7 years (20,709 days).
Specimen TCGA-CX-A4AQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45551e82-8e06-4010-801b-b2c438d86341.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CX-A4AQ-10A (Blood Derived Normal), aliquot TCGA-CX-A4AQ-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54a9b3df-8b2b-4961-a7cf-70b5279fbd8c

The open-access MAF lists 108 somatic variants for this specimen: 84 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 72, Silent 24, Frame Shift Del 5, Nonsense Mutation 4, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HEPACAM | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907055, CM112427, COSV100005427; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | hotspot (GDC flag); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC068580.4 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs758822108, COSV52587868; called by muse, mutect2, varscan2
- AGAP4 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101432596; called by mutect2, varscan2
- AHNAK | c.12680A>G p.D4227G | Missense Mutation (SNP) | VAF 161/395 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.215); catalogued as COSV99945412; called by muse, mutect2, varscan2
- AKAP13 | c.7138G>C p.E2380Q (on ENST00000394518 / NM_007200.5; = p.E2384Q on NM_006738.6) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.571); catalogued as COSV100773066; called by muse, mutect2, varscan2
- APOB | c.2542A>T p.I848L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99263382; called by muse, mutect2, varscan2
- ARHGAP33 | c.3254G>C p.G1085A | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV50125784, COSV99137522; called by muse, mutect2
- ASTN1 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.916); catalogued as COSV99920336; called by muse, mutect2
- C1R | c.1630A>T p.M544L (on ENST00000536053 / NM_001354346.2; = p.M530L on NM_001733.7) | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV101605603; called by muse, mutect2, varscan2
- CCN1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989294037, COSV71704353; called by muse, mutect2, varscan2
- CNTNAP5 | c.1303C>G p.R435G | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as rs762380196, COSV101443000, COSV70478849; called by muse, varscan2
- COL22A1 | c.4802C>T p.P1601L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs974691796, COSV57340741; called by muse, mutect2
- CSNK1D | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.051); catalogued as rs571020217, COSV99484361; called by muse, varscan2
- CYLD | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV61094920; called by muse, mutect2, varscan2
- CYRIA | c.38A>C p.E13A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100838215; called by muse, mutect2, varscan2
- DRD3 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99879128; called by muse, mutect2, varscan2
- DUSP6 | c.598T>A p.S200T | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs749843803, COSV54379926; called by muse, mutect2, varscan2
- EXT2 | c.1082C>T p.A361V (on ENST00000343631; = p.A394V on NM_000401.3) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV100640502; called by muse, mutect2, varscan2
- FABP2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.635); catalogued as COSV99916860; called by muse, mutect2, varscan2
- FGD5 | c.2977C>T p.H993Y | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs749054617, COSV99547179; called by muse, mutect2, varscan2
- GCDH | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM980866, COSV53366414, COSV99535676; called by muse, mutect2, varscan2
- GNRHR | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56933488; called by muse, mutect2, varscan2
- GPRIN2 | c.1118A>G p.E373G | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV100966279; called by muse, mutect2
- GTF3C4 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV100935888; called by muse, mutect2, varscan2
- H1-4 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56802015; called by muse, mutect2, varscan2
- HELZ | c.3826C>T p.Q1276* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100698485; called by muse, mutect2, varscan2
- HIVEP1 | c.7979C>T p.T2660M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs762472721, COSV101044627; called by muse, mutect2, varscan2
- HYDIN | c.11242C>T p.R3748C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs12102644, COSV66638865; called by muse, mutect2, varscan2
- IL17RD | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1230169111, COSV56340957; called by muse, mutect2, varscan2
- IPP | c.353A>T p.Q118L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV100739362; called by muse, mutect2, varscan2
- KDSR | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100430156; called by muse, mutect2, varscan2
- KIAA1755 | c.3392G>T p.G1131V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99641426; called by muse, mutect2, varscan2
- LDOC1 | c.47A>G p.H16R | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100983127; called by muse, mutect2, varscan2
- LZTS1 | c.1740C>A p.D580E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV99742613; called by muse, mutect2, varscan2
- MUC5B | c.10828G>A p.E3610K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as rs1225550006, COSV101500003; called by muse, mutect2, varscan2
- OBSL1 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216138; called by muse, mutect2, varscan2
- OR2B2 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100308030, COSV100308096; called by muse, mutect2, varscan2
- OR5L1 | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 74/345 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.372); catalogued as COSV100449899; called by muse, mutect2, varscan2
- OR8I2 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100135840; called by muse, mutect2, varscan2
- PCDHB2 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52028944; called by muse, mutect2, varscan2
- PCSK5 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV65089174; called by muse, mutect2, varscan2
- PDE4DIP | c.6865C>T p.Q2289* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as rs1173338428, COSV100516226; called by muse, mutect2, varscan2
- PGAP6 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV99170570; called by muse, mutect2, varscan2
- PLCL2 | c.3362C>T p.A1121V (on ENST00000615277 / NM_001144382.2; = p.A995V on NM_015184.5) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.48); catalogued as COSV101371993; called by muse, mutect2, varscan2
- PPEF1 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100583510; called by muse, mutect2, varscan2
- PRELP | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs137872837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCD3 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99605955; called by muse, mutect2, varscan2
- RELN | c.902+2T>C p.X301_splice | Splice Site (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100632235; called by muse, mutect2, varscan2
- RGPD2 | c.5212G>A p.G1738R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100552883; called by mutect2, varscan2
- RNPS1 | c.633G>C p.E211D | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV100067212, COSV100067663; called by muse, mutect2, varscan2
- S100A4 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100573014; called by muse, mutect2, varscan2
- SCRIB | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1321126046, COSV100252449; called by muse, mutect2, varscan2
- SLFN11 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.065); catalogued as COSV100390320, COSV100391103; called by muse, mutect2, varscan2
- SPANXN2 | c.190A>C p.N64H | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT tolerated (0.57); PolyPhen benign (0.1); catalogued as COSV100979766; called by muse, varscan2
- SPATA16 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs144595913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUFU | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs753862598, COSV100882849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNGAP1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs748333558, COSV99537778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNJ1 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100448892, COSV59150672; called by muse, mutect2, varscan2
- TBC1D9 | c.3390G>A p.M1130I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.065); catalogued as COSV101464253; called by muse, mutect2, varscan2
- TEX55 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV99817273; called by muse, mutect2, varscan2
- THSD7A | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV101448532, COSV104436544; called by muse, mutect2, varscan2
- TLCD1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780204233, COSV52044120; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4597A>G p.S1533G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100835778; called by muse, mutect2, varscan2
- TNR | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs545876617, COSV54884756; called by muse, mutect2, varscan2
- TRIM67 | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100792023; called by muse, mutect2, varscan2
- TRIT1 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV100381338, COSV57550718; called by muse, mutect2, varscan2
- TRPM5 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99329467; called by muse, mutect2, varscan2
- TSC2 | c.2933G>A p.R978H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs876660733, COSV54768297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.28865A>T p.E9622V (on ENST00000591111; = p.E8695V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | PolyPhen benign (0.006); catalogued as COSV100592828; called by muse, mutect2
- USP11 | c.976-1G>T p.X326_splice (on ENST00000218348; = p.X283_splice on NM_001371072.1) | Splice Site (SNP) | VAF 14/23 reads (61%) | catalogued as COSV99510624; called by muse, mutect2, varscan2
- UTP18 | c.1405A>G p.I469V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs1295989341, COSV99834613; called by muse, mutect2, varscan2
- WDR19 | c.2638A>G p.K880E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99975147; called by muse, mutect2, varscan2
- ZNF436 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58359002; called by muse, mutect2, varscan2
- ZNF436 | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100010844, COSV58358137; called by muse, mutect2, varscan2
- ZNF486 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100631055; called by muse, mutect2, varscan2
- ADGRF1 | c.181_197del p.E61Kfs*18 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- ETV6 | c.240_243del p.P81Lfs*8 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- GAGE1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HELZ | c.4906_4908del p.D1636del | In Frame Del (DEL) | VAF 20/207 reads (10%) | called by mutect2, pindel
- NOTCH2 | c.5089del p.V1697* | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- NWD1 | c.4382_4391del p.S1461Mfs*5 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- PUM1 | c.646_664del p.G216Wfs*5 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- TRBV30 | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
- ADCY2 | c.1494G>A p.L498= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100601670; called by muse, mutect2, varscan2
- AMACR | c.261A>G p.K87= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100162790; called by muse, mutect2, varscan2
- CACNG4 | c.663C>T p.F221= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as COSV100047319; called by muse, mutect2, varscan2
- FZD5 | c.1410C>T p.Y470= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1481612443, COSV54944954; called by muse, mutect2, varscan2
- GGTLC2 | c.294C>T p.F98= | Silent (SNP) | VAF 70/144 reads (49%) | catalogued as rs866773529, COSV67854146; called by muse, mutect2, varscan2
- HYKK | c.468G>A p.K156= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100856410; called by muse, mutect2, varscan2
- ITIH6 | c.1938C>T p.S646= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV99512792; called by muse, mutect2, varscan2
- METTL15 | c.438C>T p.F146= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100327833; called by muse, mutect2, varscan2
- MS4A1 | c.228C>T p.I76= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as COSV100619261; called by muse, mutect2, varscan2
- NELL1 | c.2070C>T p.V690= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV100118681; called by muse, mutect2, varscan2
- NUDT4 | c.216A>G p.G72= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100455686; called by muse, mutect2, varscan2
- NUF2 | c.9T>A p.T3= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV99616049; called by muse, mutect2, varscan2
- OR2G6 | c.681G>A p.R227= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV58575664; called by muse, mutect2, varscan2
- PCDHB10 | c.1692G>A p.P564= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV53376910; called by muse, mutect2, varscan2
- PDZRN3 | c.1293G>A p.L431= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs1054811455, COSV99727176; called by muse, mutect2, varscan2
- PLA2G7 | c.774G>T p.L258= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99221103; called by mutect2, varscan2
- PRDM9 | c.1752G>A p.E584= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs1282491691, COSV99689723; called by muse, mutect2, varscan2
- RAD51AP2 | c.3168T>C p.N1056= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs756432121, COSV101208276; called by muse, mutect2, varscan2
- SALL3 | c.1506G>T p.S502= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs774287520, COSV101609926; called by muse, mutect2, varscan2
- SH3TC1 | c.2430G>T p.T810= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs759285665, COSV55281956, COSV99794354; called by muse, mutect2, varscan2
- SYNE2 | c.6294G>A p.E2098= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs372331503; called by muse, mutect2, varscan2
- TADA3 | c.342G>A p.P114= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs926691443, COSV99809314; called by muse, mutect2, varscan2
- TRAM1L1 | c.231C>G p.V77= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100161980; called by muse, mutect2, varscan2
- ZNF404 | c.888G>A p.E296= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100182258; called by muse, mutect2, varscan2
